Somatic mutation profile of tumor specimen TARGET-10-PARENW-09A (aliquot TARGET-10-PARENW-09A-01D) from TARGET case TARGET-10-PARENW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.5 years (6,376 days).
Specimen TARGET-10-PARENW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa75253b-cc61-4634-97de-f4f65c79a94d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARENW-10A (Blood Derived Normal), aliquot TARGET-10-PARENW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1672f21f-ff53-4162-9ac8-6b6616d7b97b

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NBPF9 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs1553248088; called by mutect2, varscan2
- NCOA5 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.778); catalogued as COSV51644655; called by muse, mutect2
- NPAT | c.2821G>T p.V941L | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs1565309286; called by muse, mutect2
- TECTA | c.900C>A p.S300R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1262222510; called by muse, mutect2
- CFHR4 | c.1295A>T p.N432I (on ENST00000367416 / NM_001201551.2; = p.N186I on NM_006684.5) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FAM120C | c.2179T>A p.W727R | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRR3 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- HEATR5A | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- LYST | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR52M1 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PDZD2 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKDREJ | c.4830G>T p.W1610C | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNKS2 | c.2978A>T p.N993I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TRGV2 | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- TRIOBP | c.5939C>A p.A1980D (on ENST00000644935 / NM_001039141.3; = p.A267D on NM_007032.5) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PDILT | c.402C>T p.S134= | Silent (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- SLC17A8 | c.390C>T p.G130= | Silent (SNP) | VAF 71/188 reads (38%) | called by muse, mutect2, varscan2
- SPATS2 | c.861G>A p.A287= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as rs147628927; called by muse, mutect2, varscan2
